Gene-level copy-number profile of tumor specimen TARGET-10-PASILW-09A from TARGET case TARGET-10-PASILW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.4 years (4,535 days).
Specimen TARGET-10-PASILW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.f7d18595-ba72-5fb0-a9af-6db8604c2050.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PASILW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 359 have no estimate.
https://portal.gdc.cancer.gov/files/9d56fba5-d1f8-4cf8-843d-498515e6d460

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 595; copy number 1: 129; copy number 2: 58,996; copy number 3: 515; copy number 4: 4; copy number 6: 25.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,337,465, 4 genes: AL031432.2, RHD, SDHDP6, AL928711.1.
- chr7:38,256,337–38,292,078, 6 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11.
- chr13:48,389,567–48,444,704, 2 genes (within-gene range 0–2): LPAR6, Metazoa_SRP.
- chr14:22,011,910–22,497,718, 62 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 25 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 6 (within-gene range 2–6): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 6: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.

Autosomal genes at a single copy (total copy number 1): 129. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
